Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A5EW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A5EW-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomic Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description (Source)	Grade (source)	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					female	Caucasian (White)	Glioma		Brain, right frontal lobe	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Diffuse astrocytoma	2	n/a	n/a	n/a	none	n/a	80
					female	Caucasian (White)	Glioma		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-0-3

Astrocytoma, diffuse 9400/3
Site @ Brain, Supratentorial
C71.0

gwd 4/2/13

Source: NCI Genomic Data Commons file b0c3b250-40ce-4d2b-afe8-0ef6b21c9fbe (TCGA-P5-A5EW.604A50C0-CFE0-4D48-87ED-EFEFFAB05043.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).